Surgical pathology report (de-identified scan), TCGA case TCGA-76-6285, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6285-01A (Primary Tumor).

[page 1 of 4]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

[REDACTED] TCGA-76-6285

1. Brain tumor: GLIOLASTOMA, WHO GRADE IV.
2. Brain tumor: GLIOBLASTOMA, WHO GRADE IV.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Tumor necrosis is present. Microvascular proliferation is also identified in the tumor. Tumor cells show positive immunohistochemical staining for GFAP. The proliferation index in areas of the tumor is extremely high. Areas of the tumor on slide 1B have a Ki67 proliferation index of approximately 60%. Rare macrophages are present in the vicinity of tumor necrosis and these macrophages show positive immunohistochemical staining for CD68.

A separate report with the results of FISH analysis for 1p19q deletion will be issued.

Frozen Section Diagnosis:

1. Brain tumor: Glioblastoma. Frozen section diagnosis by [REDACTED]

Clinical History and Diagnosis:
Left temporal brain tumor

Source of Specimen:

- 1: Brain tumor
- 2: Brain tumor

Gross Description:

[REDACTED]

[page 2 of 4]
1. Brain tumor: Received fresh in a specimen container labeled with the patient's name are two fragments of tan-yellow tissue measuring 0.5 x 0.4 x 0.3 cm and 0.4 x 0.4 x 0.3 cm. Touch preparations are made. Both fragments are bisected and a representative half is submitted for frozen section. The remainder is entirely submitted for permanent section.

A. FSCB. Remaining halves

2. Brain tumor: Received in formalin, in a specimen container labeled with the patient's name and "#2 brain tumor", are 3 fragments of soft tan tissue ranging from 0.5 to 0.8-cm in greatest dimension, and measuring 1.1 x 1.1 x 0.4 cm in aggregate. The specimen is entirely submitted in one cassette.

Histology Laboratory
H&E

TCGA-76-6285

[page 3 of 4]
Patient: [REDACTED]

MOLECULAR PATHOLOGY REPORT

[REDACTED] TCGA-76-6285

EVALUATION:

ASSAY PERFORMED: del(1p)del(19q) BY FLUORESCENT IN-SITU HYBRIDIZATION (FISH)

RESULT: nuc ish 1p36(P73 x 1~2),1q24(ANGPTL1 x 1~3) [200],19p13(ZNF44 x 1~3),19q13(GLTSCR x 1~2) [200]

1p36/1q24

Number of Nuclei scored - 200

Ratio of 1p/1q 0.57

% cells with del 1p 79%

19q13/19p13

Number of Nuclei scored - 200

Ratio of 19q/19p 0.59

% cells with del 19q 74%

INTERPRETATION: The results are less than the normal range and suggest deletions of 1p and 19q in this glioblastoma multiforme [REDACTED] del (1p) and del(19q) has been observed in glioma specimens, especially oligodendrogliomas. Clinical and pathologic correlation is recommended.

DESCRIPTION OF THE ASSAY: 1p and 19q FISH studies were performed on paraffin embedded tumor sections. Two hybridizations were performed: one with a 1p/1q probe/control pair and one with a 19q/19p probe/control pair. The 19q and 1p probes map to regions that are commonly deleted in gliomas. The nuclei are counterstained with DAPI and the cells examined by epi-fluorescence microscopy. The total number of counts for each probe is determined in 200 cells and the ratios of 1p/1q and 19q/19p are calculated.

Normal range: The normal ratio is approximately 1. Any ratio > 0.80 is considered normal.

LIMITATIONS: Low levels of malignant cells in the specimen can result in a false negative result. As with all laboratory tests, sampling error and other factors may affect the outcome of the assay. Correlation of results with other clinical and laboratory data should be obtained.

COMMENT: This test was developed and its performance characteristics determined by the [REDACTED]

[REDACTED] It has not been cleared or approved by the U.S.

[page 4 of 4]
[REDACTED]
Food and Drug Administration.

This test is not to be used as a diagnostic procedure without confirmation of the diagnosis by another medically established product or procedure.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Data Analysis:

Photodocumentation: 2 each probe set

Clinical History and Diagnosis:
Glioblastoma WHO Grade IV

Source of Specimen:

1: FISH-BRAIN

Gross Description:

[REDACTED]
Formalin fixed paraffin-embedded tissue

Histology Laboratory

H&E

Source: NCI Genomic Data Commons file 6dcab201-e07e-466a-81b2-040a24feab4f (TCGA-76-6285.9B0A966E-0CD8-44A2-8F15-C5F5ED40C189.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).